Clinical report (de-identified scan), EXCEPTIONAL_RESPONDERS case ER-AD0W, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders), specimen ER-AD0W-TTP1-A (Primary Tumor).

[page 1 of 36]
Anatomic Pathology Results Posted by Result Date (Reverse Chronological Order):
Please review all results carefully. This report does not flag clinically significant results.

Result Date/Time: [REDACTED]

FINAL REPORT

SURG PATH FINAL REPORT

SURGICAL PATHOLOGY

Collected: [REDACTED] +0
Accession: [REDACTED]
Physician: [REDACTED]

PROCEDURE

EGD and biopsy

HISTORY

Three month history of profound weight loss, dysphagia and abdominal discomfort. CT scan revealed gastric wall thickening suspicious for neoplasm, enlarged para-aortic lymph nodes, and pulmonary nodules suspicious for metastatic neoplasm. EGD revealed a mass in the stomach from the distal esophagus to the lesser curvature.

GROSS

- A. "Stomach." Multiple bits up to 0.3 cm. All processed - 1 cassette.
- B. "Esophagus." Multiple bits up to 0.3 cm. All processed - 1 cassette.

DIAGNOSIS

STOMACH: INVASIVE ADENOCARCINOMA, FAVOR GASTRIC CARCINOMA.

ESOPHAGUS: INVASIVE ADENOCARCINOMA, FAVOR GASTRIC CARCINOMA.

COMMENT

Both sets of biopsies show columnar mucosa consistent with gastric cardia giving rise to poorly differentiated adenocarcinoma. No squamous mucosa is present.

Carcinoma cells demonstrate focal positive staining for CK7 and CDX2, with negative expression for CK20, synaptophysin, chromogranin, TTF-1, and Her2/Neu. These results support a primary gastric neoplasm with esophageal involvement. There is no associated Barrett mucosa.

Two other gastrointestinal pathologists have reviewed this case and concur.

+4

(Electronic Signature) [REDACTED]

Result Date/Time: [REDACTED] +0

FINAL REPORT

SURG PATH PRELIMINARY REPORT

SURGICAL PATHOLOGY

Collected: [REDACTED] +0
Accession: [REDACTED]
Physician: [REDACTED]

PROCEDURE

EGD and biopsy.

PRELIMINARY FINDINGS

Both esophagus and stomach exhibit invasive carcinoma with features of adenocarcinoma and in other areas, a neuroendocrine carcinoma. Immunostains and additional opinions will be obtained. Anticipated date of final report is [REDACTED] +4

[page 2 of 36]
[REDACTED]

(Electronic Signature)

[REDACTED]

[REDACTED]

+5

[page 3 of 36]
CT Abd and Pelvis w Contrast

* Final Report *

* Final Report *

Reason For Exam
ABDOMINAL PAIN / NAUSEA

REPORT

CT ABDOMEN AND PELVIS WITH CONTRAST

CLINICAL INDICATION: Vomiting, nausea, abdominal pain, pressure.

PROCEDURE: Routine abdomen and pelvis CT after oral and 100 mL of Isovue-370 nonionic intravenous contrast.

FINDINGS: There are multiple small noncalcified nodules in the lung bases. These are incompletely evaluated. This is felt to likely represent pulmonary metastatic disease given findings in the abdomen.

There is a small hiatal hernia present. There is marked wall thickening of the upper stomach involving the cardia and a portion of the fundus of the stomach extending to the GE junction. Findings concerning for gastric wall neoplasm. There does appear to be small adjacent adenopathy in this region although this is difficult to assess due to a paucity of intraabdominal fat. There are noted to be enlarged lymph nodes in the paraaortic region on the left, the largest measuring 5.1 x 3.8 x 3.2 cm on image [REDACTED] and coronal image [REDACTED] with a smaller node seen medial to this on image [REDACTED] measuring approximately 1.6 x 1.4 cm. There is a small aortocaval node seen on coronal image [REDACTED] and image [REDACTED] which measures approximately 0.8 x 1.4 cm. The bowel was nonobstructive. The liver, spleen, adrenal glands and kidneys are unremarkable. No pelvic mass is noted. Urinary bladder is decompressed.

IMPRESSION: Abnormal study. Findings consistent with likely gastric neoplasm with intraabdominal metastatic disease and large adenopathy noted in the left paraaortic region and aortocaval region. Multiple small noncalcified pulmonary nodules noted concerning for pulmonary metastatic disease. See above.

Stat Faxed to [REDACTED]

Printed by: [REDACTED]
Printed on: [REDACTED]

Page 1 of 2
(Continued)

[page 4 of 36]
CT Abd and Pelvis w Contrast

* Final Report *

Reading Location: [redacted]

Type:	CT Abd and Pelvis w Contrast	
Date:	[redacted]	-21
Status:	Auth (Verified)	
Title:	CT Abd and Pelvis w Contrast	
By:	[redacted]	-21
Verified By:	[redacted]	-21
Encounter info:	[redacted]	

[page 5 of 36]
XR Chest 2 Views

* Final Report *

*** Final Report ***

Reason For Exam

Cough

REPORT

TWO VIEW CHEST () :

DATE OF EXAMINATION: -25

CLINICAL INDICATION: Cough. Shortness of breath and weight loss.

COMPARISON: None.

Two views demonstrate clear lungs. The cardiovascular silhouette has a satisfactory appearance. Pulmonary vasculature within normal limits. Pleural spaces are clear.

IMPRESSION:

1. No acute process.

Reading Location:

Printed by:
Printed on:

[page 6 of 36]
XR Chest 2 Views

* Final Report *

Type: XR Chest 2 Views
Date: -25
Status: Auth (Verified)
Title: XR Chest 2 Views
By: -25
Verified By: -24
Encounter info:

[page 7 of 36]
CT Abd and Pelvis w Contrast

* Final Report *

* Final Report *

Reason For Exam

ASSESS RESPONSE TO TX MESTASTIC GASTRIC CANCER

REPORT

CT Abd and Pelvis w Contrast, CT Chest w Contrast

CT DATED: [REDACTED] +73

CLINICAL HISTORY: Reason for Study: ASSESS RESPONSE TO TX MESTASTIC GASTRIC CANCER
Additional Comments:

-21

COMPARISON: [REDACTED] abdomen and pelvis 18

PROCEDURE: Routine chest, abdomen and pelvis CT after the administration of oral contrast and 100 mLs of nonionic intravenous contrast

FINDINGS:

Scattered bilateral ill-defined pulmonary nodules and semisolid densities. Improving from prior. Some residua. Compatible with improving metastatic disease. See 4 mm nodule in the lingula on image 51 compared to 6 or 7 mm previously. Many prior nodules are now only faintly visible.

No pleural effusion.

Left chest wall port.

Mildly prominent middle mediastinal lymph nodes are borderline prominent size. See for example precarinal 1.0 x 1.5 cm lymph node on image 25.

Mildly prominent wall thickness in distal esophagus and the gastric cardia. Significantly improved from prior when there is extensive neoplasm in this area. There continues to be infiltration into the adjacent fat, as for example adjacent to gastric cardia and into gastrohepatic ligament. The region is not reliably measured although 4 general reference purposes an example is image 62 where the general region of thickening and infiltration spans 6.1 x 5.1 cm compared to previously and perhaps 9 x 7 cm.

Liver unremarkable

Gallbladder unremarkable. The pancreas itself is probably acceptable. The superior aspect of its body may contact infiltrative tumor from the stomach.

Spleen adrenal glands and kidneys unremarkable.

Urinary bladder and prostate unremarkable.

Nonobstructive bowel

Printed by:
Printed on:

Page 1 of 3
(Continued)

[page 8 of 36]
CT Abd and Pelvis w Contrast

* Final Report *

Abdominal left para-aortic neoplastic adenopathy is again identified. Improving. See for example image [REDACTED] where a left para-aortic lymph node measures 3.0 x 1.5 cm compared to 4.5 x 3.1 cm.

IMPRESSION:

1. Significant improvement in neoplastic disease burden.
2. Gastroesophageal junction to gastric cardia bulky tumor mass infiltrating surrounding soft tissue remains present but is significantly improved.
3. Neoplastic adenopathy in the abdominal retroperitoneum remains, but is significantly improved.
4. Widespread pulmonary metastases remain, but are significantly improved.
5. Mild mediastinal lymphadenopathy. Not comparable to prior. Whether its neoplastic is not established.
6. No definite neoplastic disease progression

Electronically reviewed and signed by: [REDACTED] [REDACTED] +73
Reading Location: [REDACTED]

[page 9 of 36]
CT Abd and Pelvis w Contrast

* Final Report *

Type:	CT Abd and Pelvis w Contrast	
Date:	[Redacted]	+73
Status:	Auth (Verified)	
Title:	CT Abd and Pelvis w Contrast	
By:	[Redacted]	+73
Verified By:	[Redacted]	+73
Encounter info:	[Redacted]	

[page 10 of 36]
CT Chest w Contrast

* Final Report *

* Final Report *

Reason For Exam

HX OF GASTRIC CA; RESTAGING

REPORT

CT Abd and Pelvis w Contrast, CT Chest w Contrast

COMPLETED DATE: [REDACTED] +794

CLINICAL HISTORY: HX OF GASTRIC CA; RESTAGING

ADDITIONAL COMMENTS: None Provided
+693, +579

COMPARISON: [REDACTED] and prior

PROCEDURE: Routine chest, abdomen and pelvis CT after the administration of oral contrast and 100 mL of nonionic intravenous contrast

FINDINGS:

Chest CT:

Stable 5 mm nodule opacity in the lingula, image 2:45. Stable 4 mm nodular thickening along the right major fissure, image 2:26. Stable 3 mm irregular pleural-based opacity right middle lobe anteriorly. No new or enlarging pulmonary nodules. No acute airspace disease, pneumothorax or pleural effusion.

Stable 7 mm lymph node in the right. Esophageal region, image 2:54. Nonenlarged mediastinal lymph nodes are stable. No new or enlarging hilar or mediastinal lymph nodes identified. Left subcutaneous central venous catheter is again identified with tip in the SVC.

Abdominal and pelvic CT:

Mild thickening along the gastroesophageal junction is stable. Remainder the bowel and mesentery are unremarkable. Liver, spleen, pancreas, kidneys and adrenal glands are unremarkable. Mildly enlarged left periaortic lymph node appears stable measuring 1 cm in short axis on image 2:88. No new or enlarging lymph nodes through the abdomen or pelvis. No other mass lesions or abnormal fluid collections identified. Prostate, seminal vesicles and urinary bladder are unremarkable. No suspicious lytic or sclerotic osseous lesions.

IMPRESSION:

1. Stable 5 mm nodule in the lingula and 4 mm nodular thickening along the right major fissure. No new or enlarging pulmonary nodules.
2. Stable mild thickening along the gastroesophageal junction.
3. Stable mildly prominent left periaortic lymph node with short axis of 10 mm. No new or enlarging adenopathy within the abdomen or pelvis.

Printed by:
Printed on:

Page 1 of 2
(Continued)

[page 11 of 36]
CT Chest w Contrast

* Final Report *

Electronically reviewed and signed by: +794
Reading Location:

Type: CT Chest w Contrast
Date: +794
Status: Auth (Verified)
Title: CT Chest w Contrast
By: +794
Verified By: +794
Encounter info:

[page 12 of 36]
CT Abd and Pelvis w Contrast

* Final Report *

* Final Report *

Reason For Exam

HX OF GASTRIC CA; RESTAGING

REPORT

CT Abd and Pelvis w Contrast, CT Chest w Contrast

COMPLETED DATE: [REDACTED] +794

CLINICAL HISTORY: HX OF GASTRIC CA; RESTAGING

ADDITIONAL COMMENTS: None Provided
+693, +579

COMPARISON: [REDACTED], [REDACTED] and prior

PROCEDURE: Routine chest, abdomen and pelvis CT after the administration of oral contrast and 100 mL of nonionic intravenous contrast

FINDINGS:

Chest CT:

Stable 5 mm nodule opacity in the lingula, image 2:45. Stable 4 mm nodular thickening along the right major fissure, image 2:26. Stable 3 mm irregular pleural-based opacity right middle lobe anteriorly. No new or enlarging pulmonary nodules. No acute airspace disease, pneumothorax or pleural effusion.

Stable 7 mm lymph node in the right. Esophageal region, image 2:54. Nonenlarged mediastinal lymph nodes are stable. No new or enlarging hilar or mediastinal lymph nodes identified. Left subcutaneous central venous catheter is again identified with tip in the SVC.

Abdominal and pelvic CT:

Mild thickening along the gastroesophageal junction is stable. Remainder the bowel and mesentery are unremarkable. Liver, spleen, pancreas, kidneys and adrenal glands are unremarkable. Mildly enlarged left periaortic lymph node appears stable measuring 1 cm in short axis on image 2:88. No new or enlarging lymph nodes through the abdomen or pelvis. No other mass lesions or abnormal fluid collections identified. Prostate, seminal vesicles and urinary bladder are unremarkable. No suspicious lytic or sclerotic osseous lesions.

IMPRESSION:

1. Stable 5 mm nodule in the lingula and 4 mm nodular thickening along the right major fissure. No new or enlarging pulmonary nodules.
2. Stable mild thickening along the gastroesophageal junction.
3. Stable mildly prominent left periaortic lymph node with short axis of 10 mm. No new or enlarging adenopathy within the abdomen or pelvis.

Printed by:
Printed on:

Page 1 of 2
(Continued)

[page 13 of 36]
CT Abd and Pelvis w Contrast

[Redacted]

* Final Report *

[Redacted]

Electronically reviewed and signed by: [Redacted] +794
Reading Location: [Redacted]

[Redacted]

Type:	CT Abd and Pelvis w Contrast	
Date:	[Redacted]	+794
Status:	Auth (Verified)	
Title:	CT Abd and Pelvis w Contrast	+794
By:	[Redacted]	+794
Verified By:	[Redacted]	
Encounter info:	[Redacted]	

[page 14 of 36]
CT Abd and Pelvis w Contrast

* Final Report *

* Final Report *

Reason For Exam

CHEST, ABD, PEL WITH CONTRAST RESTAGING HX OF COLON CA

REPORT

CT Chest w Contrast, CT Abd and Pelvis w Contrast

COMPLETED DATE: [REDACTED] +693

CLINICAL HISTORY: CHEST, ABD, PEL WITH CONTRAST RESTAGING HX OF COLON CA

ADDITIONAL COMMENTS: Gastric cancer.

COMPARISON: [REDACTED] +579

PROCEDURE: Routine chest, abdomen and pelvic CT after the administration of oral intravenous contrast and 100 mL of nonionic intravenous contrast.

FINDINGS:

CHEST:

AORTA: Moderate atherosclerotic calcifications seen in the infrarenal abdominal aorta and iliac.

MEDIASTINUM AND HILA: No enlarged axillary lymph nodes. Nonenlarged pretracheal lymph nodes are unchanged from the prior study. No suspicious hilar adenopathy. A 7 mm lower paraesophageal lymph node is stable from the prior study on series 2:55.

HEART: No pericardial effusion.

LUNGS: 5 mm left upper lobe pulmonary nodule series 2:47 unchanged. Triangular subpleural opacity in the anterior right upper lobe series 2:42 is unchanged, likely due to atelectasis. No new or suspicious pulmonary nodule.

PLEURAL SPACES: No pneumothorax or pleural effusion.

ABDOMEN AND PELVIS:

LIVER: Normal.

BILIARY SYSTEM: No intrahepatic or extrahepatic dilation.

GALLBLADDER: No calcified stone.

PANCREAS: Normal.

SPLEEN: Borderline/mildly enlarged measuring 13 cm, unchanged from the prior study.

ADRENALS: No mass or nodule.

Printed by:
Printed on:

Page 1 of 3
(Continued)

[page 15 of 36]
CT Abd and Pelvis w Contrast

* Final Report *

KIDNEYS: Normal.

BOWEL: No dilated loops of small bowel. The colon is largely filled with stool. The appendix is normal. There is no evidence of obstruction. The mucosal thickening and hyperenhancement at the GE junction and proximal stomach/fundus are unchanged.

LYMPH NODES: 10 mm left-sided para-aortic lymph node series 2:90 unchanged from the prior study. No new or enlarging lymph nodes.

PELVIC ORGANS: Bladder wall is thickened which may be due to underdistention or chronic outlet obstruction. Prostate normal.

IMPRESSION:

1. Stable appearance of the chest, abdomen and pelvis. Stable hyperenhancement and mucosal thickening at the GE junction and proximal stomach.
2. Stable distal right paraesophageal lymph node.
3. Stable 5 mm left upper lobe pulmonary nodule.

Electronically reviewed and signed by: +693
Reading Location:

Type: CT Abd and Pelvis w Contrast
Date: +693

Printed by:
Printed on:

Page 2 of 3
(Continued)

[page 16 of 36]
CT Abd and Pelvis w Contrast

* Final Report *

Status:

Auth (Verified)

Title:

CT Abd and Pelvis w Contrast

By:

Verified By:

Encounter info:

Printed by:
Printed on:

Page 3 of 3
(End of Report)

[page 17 of 36]
CT Abd and Pelvis w Contrast

* Final Report *

* Final Report *

Reason For Exam

RESTAGING, CA

REPORT

CT Chest w Contrast, CT Abd and Pelvis w Contrast

COMPLETED DATE: [REDACTED] +579

CLINICAL HISTORY: RESTAGING, CA

ADDITIONAL COMMENTS: None Provided

COMPARISON: [REDACTED] +495

PROCEDURE: Routine chest, abdomen and pelvis CT after the administration of oral contrast and 100 mLs of nonionic intravenous contrast

FINDINGS:

CHEST:

Lungs: Unchanged oblong-shaped 2 mm superior segment right lower lobe nodule on image 27. Unchanged punctate 1 mm right middle lobe nodule on image 49. Unchanged 3 mm lingular nodule on image 45. Unchanged wedge-shaped inferior lingular nodule measuring 4 mm on image 53. No new pulmonary nodule or abnormal airspace opacity.

Central airway: Widely patent and unremarkable.

Pleura: No pleural effusions, pleural thickening, or pneumothorax.

Heart: The heart is normal in size. No pericardial effusion. No significant coronary artery calcification.

Aorta: The aorta is normal in size and morphology. No significant atherosclerosis.

Pulmonary arteries: The central pulmonary arteries are unremarkable.

Lymph nodes: No enlarged thoracic lymph nodes.

Lower neck and mediastinum: Unremarkable.

Chest wall and thoracic spine: Left chest port with catheter tip in the mid SVC. No aggressive osseous lesions.

ABDOMEN/PELVIS:

The liver, spleen, adrenal glands, pancreas, gallbladder, and kidneys are unremarkable. The urinary bladder is mildly distended and unremarkable.

Printed by:
Printed on:

Page 1 of 3
(Continued)

[page 18 of 36]
CT Abd and Pelvis w Contrast

* Final Report *

No bowel wall thickening or luminal dilatation. No free air or free fluid. Tiny sliding-type hiatal hernia. Very minimal wall thickening in the region of the gastroesophageal junction, markedly improved from [REDACTED] and not significantly changed from the prior exam.

-21

No free air free fluid.

-21

Unchanged 12 x 9 mm retroperitoneal lymph node on image 89, stable from the immediate prior exam and markedly decreased from [REDACTED]. Adjacent tiny retroperitoneal lymph node is unchanged on image 87 measuring 6 mm. Additional tiny punctate retroperitoneal lymph nodes are noted and also unchanged.

Moderate atherosclerosis. The portal venous system is patent.

No aggressive osseous lesions.

IMPRESSION:

1. No major interval change from the prior exam. Very mild wall thickening involving the gastroesophageal junction is noted, unchanged from the immediate prior exam and markedly improved from more remote exams. Retroperitoneal lymph nodes have not significantly changed including a 12 mm left para-aortic lymph node. Multiple pulmonary nodules are again noted, unchanged from the prior exam. No new pulmonary nodules or enlarged lymph nodes.

Electronically reviewed and signed by: [REDACTED] [REDACTED] +579
Reading Location: [REDACTED]

Type: CT Abd and Pelvis w Contrast
Date: [REDACTED] +579

Printed by:
Printed on:

Page 2 of 3
(Continued)

[page 19 of 36]
CT Abd and Pelvis w Contrast

* Final Report *

Status:	Auth (Verified)	
Title:	CT Abd and Pelvis w Contrast	
By:		+579
Verified By:		+579
Encounter info:		

[page 20 of 36]
CT Abd and Pelvis w Contrast

* Final Report *

* Final Report *

Reason For Exam
RESTAGING STOMACH CA

REPORT

CT Abd and Pelvis w Contrast, CT Chest w Contrast

COMPLETED DATE: [REDACTED] +495

CLINICAL HISTORY: RESTAGING STOMACH CA

ADDITIONAL COMMENTS: None Provided

COMPARISON: [REDACTED] . +390

PROCEDURE: Routine chest, abdomen and pelvis CT after the administration of oral contrast and 100 mLs of nonionic intravenous contrast

FINDINGS:

The lungs are clear except for the previously described small nodules in the right middle lobe and lingula. No pleural effusion.

No mediastinal or hilar lymphadenopathy.

The liver, spleen, pancreas, adrenal glands and kidneys within normal limits.

Moderate atherosclerotic changes of the aorta without aneurysm.

No lymphadenopathy or ascites in the abdomen/pelvis.

Unchanged mild enhancement of the gastric wall and mild thickening of distal esophagus.

IMPRESSION:

1. No evidence to suggest recurrent or metastatic disease with no significant change.
2. Previously described left para-aortic lymph node is nonspecific measuring 1.2 cm.
3. The previously described small nodule in the lingula is unchanged. The previously described right middle lobe nodules have resolved. No new nodules.

Printed by:
Printed on:

Page 1 of 2
(Continued)

[page 21 of 36]
CT Abd and Pelvis w Contrast

[Redacted]

* Final Report *

Edited by: [Redacted]

Electronically reviewed and signed by: [Redacted] +495
Reading Location: [Redacted]

Type:	CT Abd and Pelvis w Contrast	
Date:	[Redacted]	+495
Status:	Auth (Verified)	
Title:	CT Abd and Pelvis w Contrast	+495
By:	[Redacted]	+495
Verified By:	[Redacted]	
Encounter info:	[Redacted]	

Printed by: [Redacted]
Printed on: [Redacted]

[page 22 of 36]
CT Abd and Pelvis w Contrast

* Final Report *

* Final Report *

Reason For Exam

HX OF STOMACH CANCER, RESTAGING

REPORT

CT Abd and Pelvis w Contrast, CT Chest w Contrast

CT DATED: [REDACTED] +390

CLINICAL HISTORY: History of gastric cancer. Presents for restaging.
+311 +73

COMPARISON: CT chest abdomen pelvis dated [REDACTED] and [REDACTED].

TECHNIQUE: Routine chest, abdomen and pelvis CT after the administration of oral contrast and 100 mLs of nonionic intravenous contrast

FINDINGS:

CHEST:

~+73

A 5 mm subpleural pulmonary nodule in the lingula on series 2 image 42 is unchanged dating back to [REDACTED]. In a probable 5 mm right middle lobe pulmonary nodule on series 2 image 48 is also unchanged. The lungs are otherwise clear. No new pulmonary nodules or masses are identified. There is no pleural effusion or pneumothorax. The tracheobronchial tree is patent.

Cardiac size is within normal limits. There is no pericardial effusion. The thoracic aorta and central pulmonary arteries are normal in caliber. A left-sided chest port terminates at the cavoatrial junction.

~+73

No pathologically enlarged lymph nodes are identified in the chest. Multiple nonenlarged mediastinal lymph nodes are unchanged in size and number dating back to [REDACTED].

ABDOMEN/PELVIS:

The liver, gallbladder, spleen, pancreas, kidneys and adrenal glands are unremarkable.

The small and large bowel are normal in caliber, there is no bowel wall thickening or mesenteric edema. There is no intraperitoneal free air or intra-abdominal fluid collection. A normal caliber appendix is visualized. A thickened appearance to the gastroesophageal junction and gastric cardia is unchanged from prior.

The urinary bladder is unremarkable. The prostate is normal in size.

The previously noted left para-aortic lymph node located just below the level of the left renal vein measures 1.5 x 1.0 cm on series 2 image 85, not significantly changed from 1.7 x 1.0 cm in [REDACTED], but decreased in size from 3.0 x 1.5 cm in [REDACTED]. No additional pathologically enlarged lymph nodes are identified the abdomen or pelvis.

~+311

~+73

Printed by:
Printed on:

Page 1 of 3
(Continued)

[page 23 of 36]
CT Abd and Pelvis w Contrast

[REDACTED]

* Final Report *

Moderate to severe calcified atherosclerotic disease involves a normal caliber abdominal aorta and the bilateral pelvic outflow vessels.

SKELETON:

No lucent or sclerotic skeletal lesion is identified in the chest, abdomen or pelvis.

IMPRESSION:

1. No CT evidence of new metastatic disease in the chest, abdomen or pelvis.
2. 5 mm nodules in the lingula and right middle lobe are unchanged dating back to [REDACTED] ~+73 [REDACTED]. No new pulmonary nodules or masses are identified.
- +311 3. A 1.5 x 1.0 cm left para-aortic lymph node is not significantly changed in size from [REDACTED], it has significantly decreased in size from [REDACTED]. No new enlarged lymph nodes are identified in the chest, abdomen or pelvis.+73
4. Unchanged nonspecific diffusely thickened appearance of the gastroesophageal junction.

[REDACTED]

Electronically reviewed and signed by: [REDACTED] [REDACTED] +390
Reading Location: [REDACTED]

[REDACTED]

Type: CT Abd and Pelvis w Contrast
Date: [REDACTED] +390

Printed by:
Printed on:

[REDACTED]

[page 24 of 36]
CT Abd and Pelvis w Contrast

* Final Report *

Status:	Auth (Verified)	
Title:	CT Abd and Pelvis w Contrast	
By:		+390
Verified By:		+390
Encounter info:		

[page 25 of 36]
* Final Report *

*** Final Report ***

Reason For Exam
RESTAGING STOMACH CA

REPORT

CT CHEST W CONTRAST, CT ABDOMEN AND PELVIS W CONTRAST:

COMPLETED DATE: [REDACTED] +311

CLINICAL HISTORY: RESTAGING STOMACH CA

ADDITIONAL COMMENTS: None Provided
+213 +129

COMPARISON: [REDACTED] and [REDACTED]

PROCEDURE: Routine chest, abdomen and pelvis CT after the administration of oral contrast and 100 mL of nonionic intravenous contrast

FINDINGS:

CHEST: Faint groundglass opacity in the right middle lobe is less prominent measuring 6 x 4 mm on image 2:43. This previous measured 9 x 6 mm. Stable 4 mm nodule in the right middle lobe image 2:53. Stable ill-defined 6 mm nodule in the lingula, image 2:46. No new or enlarging pulmonary nodules identified. No pneumothorax or pleural effusion.

Stable distal lymph nodes measuring 7 mm or less in short axis. No new or large and hilar or mediastinal lymph nodes.

ABDOMEN AND PELVIS: Stable mild thickening along the gastric cardia and GE junction. Remainder of the stomach is unremarkable. Periarticular adenopathy is again identified. Left lymph node on image 2:88 is slightly decreased in size. This person measures 1.7 x 1 cm and previous measured 1.9 x 1.2 cm. Stable aorto intracaval lymph node. No new or enlarging adenopathy within the abdomen or pelvis.

Liver, spleen, pancreas, kidneys and adrenal glands are unremarkable. Prostate, seminal vesicles, urinary bladder, bowel and mesentery are unremarkable. Degenerative changes seen along the lower lumbar spine. Changes of DISH. No suspicious lytic or sclerotic osseous lesions.

IMPRESSION:

1. Decrease in the groundglass opacity within the right middle lobe. Stable small irregular nodules in the right middle lobe and lingula. No new pulmonary nodules.
2. Stable mild thickening along the gastric cardia and GE junction.
3. Slight decrease in size of a lymph node in the left periaortic region. Stable lymph node in the aorto intracaval region. No new or enlarging adenopathy through the chest,

Printed by:
Printed on:

[page 26 of 36]
CT Abd and Pelvis w Contrast

* Final Report *

abdomen and pelvis.

4. Solid upper abdominal viscera are unremarkable.

Electronically reviewed and signed by: [Redacted] [Redacted] +311
Reading Location: [Redacted]

Type:	CT Abd and Pelvis w Contrast		
Date:	[Redacted]	+311	
Status:	Auth (Verified)		
Title:	CT Abd and Pelvis w Contrast		
By:	[Redacted]	+311	
Verified By:	[Redacted]	+311	
Encounter info:	[Redacted]		

Printed by: [Redacted]
Printed on: [Redacted]

[page 27 of 36]
CT Abd and Pelvis w Contrast

* Final Report *

* Final Report *

Reason For Exam
RESTAGING STOMACH CA

REPORT

CT Chest w Contrast, CT Abdomen and Pelvis w Contrast

CT DATED: [REDACTED] +213

CLINICAL HISTORY: Reason for Study: RESTAGING STOMACH CA Additional Comments:

COMPARISON: [REDACTED] +129

PROCEDURE: Routine chest, abdomen and pelvis CT after the administration of oral contrast and 100 mLs of nonionic intravenous contrast

+129

FINDINGS: Faint ground glass vaguely nodular focus in the pulmonary middle lobe measures 0.9 x 0.6 cm on Image 40. Similar to [REDACTED]. Vaguely nodular 4 mm nodule in the pulmonary middle lobe on Image 49 is similar [REDACTED] It may be residua of prior more +129 dominant nodule of [REDACTED]. Many of those nodules have resolved or improved. A lingular nodule on Image 47 measures 6 mm which is similar to [REDACTED], but diminishment from +129 [REDACTED].

No pleural effusion.

A few mediastinal lymph nodes are present. They are borderline prominent in number and sizes, though probably yet acceptable. Precarinal lymph node measures 0.7 cm.

Left chest wall port.

Liver, gallbladder, pancreas and spleen are unremarkable.

Adrenal glands and kidneys are unremarkable.

Urinary bladder and prostate unremarkable.

Trace free fluid in pelvis.

Nonobstructive bowel.

Wall thickness in the gastric cardia is borderline prominent, as is gastroesophageal junction. It is unclear if this is related to the reported tumor.

Several periaortic lymph nodes are present as on Image 2:87 in the upper abdomen. One on the left on this image measures 1.2 x 1.9 cm which is similar to prior. No definite new or progressive abdominal and pelvic lymphadenopathy.

IMPRESSION:

1. Borderline thickening of the gastric cardia and gastroesophageal junction. Similar to prior. It is unclear if this is related to the original tumor though suspect it is..

Printed by:
Printed on:

Page 1 of 2
(Continued)

[page 28 of 36]
CT Abd and Pelvis w Contrast

* Final Report *

2. A couple of tiny lung nodules are present. Stable compared with [redacted]. In general diminished, stable and/or resolved since [redacted] suggesting they are in part improved metastatic disease. +129 -21

3. Mild abdominal retroperitoneal lymphadenopathy is compatible with neoplasm, stable since [redacted] and improved since [redacted]. +129 -21

Edited by: [redacted] +213

Electronically reviewed and signed by: [redacted] +213

Reading Location: [redacted]

Type: CT Abd and Pelvis w Contrast

Date: [redacted] +213

Status: Auth (Verified)

Title: CT Abd and Pelvis w Contrast

By: [redacted] +213

Verified By: [redacted] +213

Encounter info: [redacted]

Printed by: [redacted]

Printed on: [redacted]

[page 29 of 36]
* Final Report *

*** Final Report ***

Reason For Exam

GASTROESOPHAGEAL CANCER

REPORT

CT Abd and Pelvis w Contrast

CT DATED:

CLINICAL HISTORY: Reason for Study: GASTROESOPHAGEAL CANCER Additional Comments: .

COMPARISON: +73

PROCEDURE: Routine chest, abdomen and pelvis CT after the administration of oral contrast and 100 mLs of nonionic intravenous contrast

FINDINGS:

CT CHEST:

Stable precarinal and left paratracheal lymph nodes measuring 5-7 mm in short axis diameter.

Stable nodular groundglass opacity in the right lung base anteriorly measuring between 8 and 9 mm in short axis diameter. Slightly anterior to this is another area of nodular groundglass opacity measuring 5-6 mm. There is a subpleural left lower lobe, groundglass nodule measuring 4-5 mm in short axis diameter. The pleural spaces are clear. The osseous structures are within normal limits. Overall this is a stable imaging finding when compared to the prior study.

IMPRESSION:

1. Stable chest CT with multiple groundglass nodules and borderline enlarged mediastinal lymph nodes.

FINDINGS CT ABDOMEN AND PELVIS:

Previously identified left periaortic retroperitoneal lymph nodes are slightly smaller in size when compared to the prior study now measuring approximately 1.3 cm in short axis diameter.

There is prominence of the distal esophagus near the gastroesophageal junction when compared to the prior examination. This is stable. The liver, spleen, pancreas, adrenal and kidneys are within normal limits. There is no free intraperitoneal fluid. No pathological or retroperitoneal lymph nodes are appreciated. There is no free intraperitoneal fluid

The appendix is within normal limits.

The osseous structures are within normal limits

Printed by:
Printed on:

[page 30 of 36]
CT Abd and Pelvis w Contrast

* Final Report *

IMPRESSION CT ABDOMEN AND PELVIS:
1) Slight interval decrease in left para-aortic lymphadenopathy when compared to the prior study.

Edited by: [redacted] +159

Edited: Added report to accession.

Electronically reviewed and signed by: [redacted] +164
Reading Location: [redacted]

Type:	CT Abd and Pelvis w Contrast	
Date:	[redacted]	+129
Status:	Auth (Verified)	
Title:	CT Abd and Pelvis w Contrast	+159
By:	[redacted]	+164
Verified By:	[redacted]	
Encounter info:	[redacted]	

Printed by: [redacted]
Printed on: [redacted]

[page 31 of 36]
CT Abd and Pelvis w Contrast

* Final Report *

* Final Report *

Reason For Exam

ASSESS RESPONSE TO TX MESTASTIC GASTRIC CANCER

REPORT

CT Abd and Pelvis w Contrast, CT Chest w Contrast

CT DATED: [REDACTED] +73

CLINICAL HISTORY: Reason for Study: ASSESS RESPONSE TO TX MESTASTIC GASTRIC CANCER
Additional Comments:

-21

COMPARISON: [REDACTED] abdomen and pelvis 18

PROCEDURE: Routine chest, abdomen and pelvis CT after the administration of oral contrast and 100 mLs of nonionic intravenous contrast

FINDINGS:

Scattered bilateral ill-defined pulmonary nodules and semisolid densities. Improving from prior. Some residua. Compatible with improving metastatic disease. See 4 mm nodule in the lingula on image 51 compared to 6 or 7 mm previously. Many prior nodules are now only faintly visible.

No pleural effusion.

Left chest wall port.

Mildly prominent middle mediastinal lymph nodes are borderline prominent size. See for example precarinal 1.0 x 1.5 cm lymph node on image 25.

Mildly prominent wall thickness in distal esophagus and the gastric cardia. Significantly improved from prior when there is extensive neoplasm in this area. There continues to be infiltration into the adjacent fat, as for example adjacent to gastric cardia and into gastrohepatic ligament. The region is not reliably measured although 4 general reference purposes an example is image 62 where the general region of thickening and infiltration spans 6.1 x 5.1 cm compared to previously and perhaps 9 x 7 cm.

Liver unremarkable

Gallbladder unremarkable. The pancreas itself is probably acceptable. The superior aspect of its body may contact infiltrative tumor from the stomach.

Spleen adrenal glands and kidneys unremarkable.

Urinary bladder and prostate unremarkable.

Nonobstructive bowel

Printed by:
Printed on:

Page 1 of 3
(Continued)

[page 32 of 36]
* Final Report *

Abdominal left para-aortic neoplastic adenopathy is again identified. Improving. See for example image [REDACTED] where a left para-aortic lymph node measures 3.0 x 1.5 cm compared to 4.5 x 3.1 cm.

IMPRESSION:

1. Significant improvement in neoplastic disease burden.
2. Gastroesophageal junction to gastric cardia bulky tumor mass infiltrating surrounding soft tissue remains present but is significantly improved.
3. Neoplastic adenopathy in the abdominal retroperitoneum remains, but is significantly improved.
4. Widespread pulmonary metastases remain, but are significantly improved.
5. Mild mediastinal lymphadenopathy. Not comparable to prior. Whether its neoplastic is not established.
6. No definite neoplastic disease progression

Electronically reviewed and signed by: [REDACTED] [REDACTED] +73
Reading Location: [REDACTED]

[page 33 of 36]
CT Abd and Pelvis w Contrast

* Final Report *

Type:	CT Abd and Pelvis w Contrast		
Date:		+73	
Status:	Auth (Verified)		
Title:	CT Abd and Pelvis w Contrast	+73	
By:		+73	
Verified By:			
Encounter info:			

[page 34 of 36]
CT Abd and Pelvis w Contrast

* Final Report *

* Final Report *

Reason For Exam
ABDOMINAL PAIN / NAUSEA

REPORT

CT ABDOMEN AND PELVIS WITH CONTRAST

CLINICAL INDICATION: Vomiting, nausea, abdominal pain, pressure.

PROCEDURE: Routine abdomen and pelvis CT after oral and 100 mL of Isovue-370 nonionic intravenous contrast.

FINDINGS: There are multiple small noncalcified nodules in the lung bases. These are incompletely evaluated. This is felt to likely represent pulmonary metastatic disease given findings in the abdomen.

There is a small hiatal hernia present. There is marked wall thickening of the upper stomach involving the cardia and a portion of the fundus of the stomach extending to the GE junction. Findings concerning for gastric wall neoplasm. There does appear to be small adjacent adenopathy in this region although this is difficult to assess due to a paucity of intraabdominal fat. There are noted to be enlarged lymph nodes in the paraaortic region on the left, the largest measuring 5.1 x 3.8 x 3.2 cm on image [REDACTED] and coronal image [REDACTED] with a smaller node seen medial to this on image [REDACTED] measuring approximately 1.6 x 1.4 cm. There is a small aortocaval node seen on coronal image [REDACTED] and image [REDACTED] which measures approximately 0.8 x 1.4 cm. The bowel was nonobstructive. The liver, spleen, adrenal glands and kidneys are unremarkable. No pelvic mass is noted. Urinary bladder is decompressed.

IMPRESSION: Abnormal study. Findings consistent with likely gastric neoplasm with intraabdominal metastatic disease and large adenopathy noted in the left paraaortic region and aortocaval region. Multiple small noncalcified pulmonary nodules noted concerning for pulmonary metastatic disease. See above.

Stat Faxed to [REDACTED]

Printed by:
Printed on:

Page 1 of 2
(Continued)

[page 35 of 36]
CT Abd and Pelvis w Contrast

[Redacted]

* Final Report *

Reading Location: [Redacted]

Type:	CT Abd and Pelvis w Contrast		
Date:	[Redacted]	-21	
Status:	Auth (Verified)		
Title:	CT Abd and Pelvis w Contrast		
By:	[Redacted]	-21	
Verified By:	[Redacted]	-21	
Encounter info:	[Redacted]		

[page 36 of 36]
Tumor Response Assessment

Name

RE: Oncology Research Protocol

MR#:

Instructions: Please use RECIST criteria to evaluate all areas of disease. Each of these areas must be termed identically from baseline through follow up studies.

BASELINE

MOST RECENT IMAGING

*BL locations verified: X		Date/ Cycle:	Reviewed by:	Date/ Cycle:	Reviewed by:	Date/ Cycle:	Reviewed by:
			-21		+73		+794
Location/ Description of Disease		ser:im#	Measurement (mm)	ser:im#	Measurement (mm)	ser:im#	Measurement (mm)
Targeted locations Please provide bilateral measurements (≥ 1cm)	1	PARAORTIC REGION ON THE LEFT, LYMPH NODE	2-43 5.1 x 3.8 cm	86 3.0 x 1.5 cm	2-88 1.0 cm		
	2						
	3						
	4						
	5						
SUM		PR ≥ 70% BL PD ≥ 120% lowest	= 3.8 cm	= 1.5 cm	= 1.0 cm		
The 1, 2, 3, A, B, C, etc., scheme is given to be a reference tool for follow-up dictations.							
Non-target locations Please provide extent: present v. absent	A	AORTOCAVAL NODE	PRESENT	PRESENT	PRESENT		
	B	PULMONARY NODULES	PRESENT	PRESENT	PRESENT		
	C						
	D						
	E						
Radiologist:		(MD Onc to verify *BL)				+886	

PER [REDACTED] REVIEW ON [REDACTED] THESE ARE THE MEASUREMENTS (RECIST v. 1.1) FOR THE [REDACTED]

Source: NCI Genomic Data Commons file b868669e-3486-46a3-803d-de16c97051af (ER0161 ER-AD0W Clinical Report_Redacted_Sanitized.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).